Somatic mutation profile of tumor specimen TCGA-AZ-4315-01A (aliquot TCGA-AZ-4315-01A-01D-1408-10) from TCGA case TCGA-AZ-4315, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIA; Age at diagnosis: 61.2 years (22,340 days).
Specimen TCGA-AZ-4315-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9fdccdd-1b11-4a5b-a045-8bdb56399e56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AZ-4315-10A (Blood Derived Normal), aliquot TCGA-AZ-4315-10A-01D-1408-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c25ac2a3-48ee-4440-be85-0552e6c67a9e

The open-access MAF lists 7,248 somatic variants for this specimen: 5,590 protein-altering or splice-affecting, 1,512 silent, 146 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4,954, Silent 1,512, Nonsense Mutation 505, Intron 67, Splice Site 58, RNA 48, Splice Region 35, Frame Shift Ins 26, 3'UTR 10, 5'Flank 9, Frame Shift Del 8, 5'UTR 7.

Variants (750 of 7,248; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABAT | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); catalogued as rs724159992, CM101236, COSV51621049; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 20/47 reads (43%) | catalogued as rs72552780, CM031114, COSV55934426; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGPAT2 | c.299G>A p.S100N | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs764260414, CM032830, COSV58247431; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 29/127 reads (23%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- APC | c.6709C>T p.R2237* | Nonsense Mutation (SNP) | VAF 25/96 reads (26%) | catalogued as rs768922431, CM130062, COSV57327470; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARL6 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 42/141 reads (30%) | catalogued as rs104893678, CM042004, COSV60117471; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP1A2 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs28933401, CM032182, COSV63402942; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AXL | c.1550G>A p.G517D (on ENST00000301178 / NM_021913.5; = p.G508D on NM_001699.6) | Missense Mutation (SNP) | VAF 37/100 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56573323; called by muse, mutect2, varscan2
- BCL6 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 20/62 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as COSV51649761; called by muse, mutect2, varscan2
- BTK | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs128621202, CM940197, COSV58117884, COSV58122224; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHD7 | c.2959C>T p.R987* | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | catalogued as rs886040983, CM060914, COSV71109383; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLCN1 | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 50/136 reads (37%) | catalogued as rs1337473924, CM950268, COSV58367883; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLCN1 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs80356703, CM950270, COSV58369252; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- COL1A1 | c.1414C>T p.R472* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as rs72648343, CM062533, COSV56804182; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMD | c.3940C>T p.R1314* | Nonsense Mutation (SNP) | VAF 51/85 reads (60%) | catalogued as rs5030730, CM100263, CS002446, COSV63740877; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EZH2 | c.2218G>A p.E740K (on ENST00000460911 / NM_001203247.2; = p.E745K on NM_004456.5) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs397515548, CM1110546, COSV57447594, COSV57464742; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FECH | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs146269992, CM068345; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GLI1 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 14/49 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1381253752, COSV57357760; called by muse, mutect2, varscan2
- GNPTAB | c.1759C>T p.R587* | Nonsense Mutation (SNP) | VAF 53/169 reads (31%) | catalogued as rs281864982, CM100341, COSV54779098, COSV68449787; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNQ2 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs886041262, CM1311201, COSV60432443; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KLHL3 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as rs199469633, CM120723, COSV59050916; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.2233C>T p.R745* | Nonsense Mutation (SNP) | VAF 37/108 reads (34%) | catalogued as rs727503777, CM150966, COSV63281970; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 15/56 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.8547+2T>C p.X2849_splice | Splice Site (SNP) | VAF 9/23 reads (39%) | catalogued as rs1450790879, COSV101370449; ClinVar: likely pathogenic; called by muse, mutect2
- MGA | c.3724C>T p.R1242* | Nonsense Mutation (SNP) | VAF 25/80 reads (31%) | hotspot (GDC flag); catalogued as COSV54948051; called by muse, varscan2
- MSH2 | c.1738G>T p.E580* | Nonsense Mutation (SNP) | VAF 60/185 reads (32%) | hotspot (GDC flag); catalogued as rs63751411, CM981314, COSV51876952; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.7348C>T p.R2450* (on ENST00000358273 / NM_001042492.3; = p.R2429* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 68/208 reads (33%) | hotspot (GDC flag); catalogued as rs786202457, CD000998, CM000818, COSV62193225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.7909C>T p.R2637* (on ENST00000358273 / NM_001042492.3; = p.R2616* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 50/150 reads (33%) | catalogued as rs786201367, CM950853, COSV62195872; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 50/116 reads (43%) | hotspot (GDC flag); catalogued as CM126687, COSV55873676, COSV55913749; called by muse, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 32/120 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, varscan2
- PIK3CA | c.3143A>G p.H1048R | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1553826184, COSV55889761, COSV55984388; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1381C>T p.R461* (on ENST00000521381 / NM_181523.3; = p.R191* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 27/102 reads (26%) | catalogued as rs1057519838, COSV57125001; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PKHD1 | c.7696G>T p.G2566* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as rs1057516751, COSV61871527, COSV61890748; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- POLE | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519945, COSV57676103, COSV57677068, COSV57683938; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- POU1F1 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs104893759, CM031332, CM920587, COSV60155661; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PRDM14 | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 38/105 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs762086448, COSV52571818; called by muse, mutect2, varscan2
- PRKCI | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 44/158 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as rs1388201066, COSV55517137, COSV55517929; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 42/129 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- PTEN | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs121913293, CM074467, COSV64288569, COSV64310838; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RFX6 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1445567359, COSV60586495, COSV60587831; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RFX6 | c.2596C>T p.R866* | Nonsense Mutation (SNP) | VAF 23/62 reads (37%) | catalogued as rs749827445, CM1512294, COSV100263268, COSV60584562; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RXYLT1 | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 40/110 reads (36%) | catalogued as rs397514695, CM134035, COSV54168177; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.5129C>T p.S1710L (on ENST00000333535 / NM_198056.3; = p.S1709L on NM_000335.5) | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs137854604, CM002105, COSV100348348; ClinVar: not provided / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SLC25A46 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1184021143, COSV63506695; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMC1A | c.3178G>A p.E1060K | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1057521921, CM159845, COSV59128864, COSV59128934; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TECTA | c.5668C>T p.R1890C | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs121909063, CM066244, COSV50700147; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TGFBR1 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 27/87 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs111854391, CM061221, COSV66624834; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TMC1 | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs121908072, CM020521, CM070292, COSV52773373, COSV52786840; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- TP63 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 14/70 reads (20%) | catalogued as rs900140738, COSV53196111; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.76114C>T p.R25372* (on ENST00000591111; = p.R17948* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 57/163 reads (35%) | catalogued as rs869038795, CM1413533, COSV59999995; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.42769C>T p.R14257* (on ENST00000591111; = p.R6833* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 34/98 reads (35%) | catalogued as rs775186117, CM1514720, COSV59899605, COSV60000160; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- XPO1 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 19/63 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV68944577, COSV68946813; called by muse, mutect2, varscan2
- ZNF649 | c.593G>T p.R198I | Missense Mutation (SNP) | VAF 71/233 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs373638440, COSV56814561; called by muse, mutect2, varscan2
- A1BG | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.011); catalogued as rs540868706, COSV54049978; called by muse, mutect2, varscan2
- A2ML1 | c.1140T>G p.I380M | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV55289410; called by muse, mutect2, varscan2
- AADACL4 | c.248A>C p.K83T | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.536); catalogued as rs749533019, COSV66106140; called by muse, mutect2, varscan2
- AASDH | c.1325G>A p.R442Q | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1447962145, COSV52705900; called by muse, varscan2
- ABCA1 | c.4219G>A p.A1407T | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.119); catalogued as rs189206655, COSV66064966; called by muse, mutect2, varscan2
- ABCA1 | c.3503G>A p.G1168D | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.135); catalogued as COSV66065642; called by muse, mutect2, varscan2
- ABCA1 | c.1080G>T p.K360N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV66065648; called by muse, mutect2, varscan2
- ABCA1 | c.408G>T p.K136N | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV66058398; called by muse, mutect2, varscan2
- ABCA12 | c.4637G>A p.R1546H (on ENST00000272895 / NM_173076.3; = p.R1228H on NM_015657.3) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1274612827, COSV55956227, COSV55978034; called by muse, mutect2, varscan2
- ABCA12 | c.4009C>A p.P1337T (on ENST00000272895 / NM_173076.3; = p.P1019T on NM_015657.3) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.835); catalogued as COSV55956250; called by muse, mutect2, varscan2
- ABCA12 | c.3674G>A p.R1225Q (on ENST00000272895 / NM_173076.3; = p.R907Q on NM_015657.3) | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.319); catalogued as rs761166029, COSV55956266; called by muse, mutect2, varscan2
- ABCA13 | c.6476C>T p.A2159V | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.96); PolyPhen benign (0.015); catalogued as rs956486939, COSV70027547; called by muse, mutect2, varscan2
- ABCA13 | c.9343G>A p.V3115I | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs779489739, COSV71286417; called by muse, mutect2, varscan2
- ABCA13 | c.10557A>C p.K3519N | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs746677896, COSV71286420; called by muse, mutect2, varscan2
- ABCA4 | c.4900G>A p.A1634T | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as COSV100933124; called by muse, mutect2, varscan2
- ABCA5 | c.4789G>A p.E1597K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52220912; called by muse, mutect2, varscan2
- ABCA5 | c.3916C>A p.L1306I | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as rs534812777, COSV101201142; called by muse, mutect2, varscan2
- ABCA5 | c.60G>T p.K20N | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67016490, COSV67018709; called by muse, mutect2, varscan2
- ABCA6 | c.4724A>G p.Y1575C | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52637798; called by muse, mutect2, varscan2
- ABCA6 | c.2314A>G p.T772A | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.78); PolyPhen benign (0.019); catalogued as COSV52637805; called by muse, mutect2, varscan2
- ABCA7 | c.680T>C p.V227A | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV99565783; called by muse, mutect2, varscan2
- ABCA8 | c.2434C>T p.R812C | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199640898, COSV52197689, COSV52199617; called by muse, mutect2, varscan2
- ABCA8 | c.2150A>C p.K717T | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV52197191, COSV52200689; called by muse, varscan2
- ABCA8 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 48/117 reads (41%) | catalogued as COSV99285771; called by muse, mutect2, varscan2
- ABCA9 | c.2615G>A p.G872D | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV60623725; called by muse, mutect2, varscan2
- ABCA9 | c.2578G>T p.E860* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as COSV60623733; called by muse, mutect2, varscan2
- ABCB1 | c.2521G>A p.A841T | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.999); catalogued as COSV55949426; called by muse, mutect2, varscan2
- ABCB1 | c.2191A>C p.I731L | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0.04); catalogued as COSV55949434; called by muse, mutect2, varscan2
- ABCB1 | c.42G>T p.K14N | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs1390637727, COSV55944962; called by muse, mutect2, varscan2
- ABCB5 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs372984477; called by muse, mutect2, varscan2
- ABCB5 | c.1760G>A p.R587Q (on ENST00000404938 / NM_001163941.2; = p.R142Q on NM_178559.6) | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs755832012, COSV51702431; called by muse, mutect2, varscan2
- ABCC1 | c.983G>A p.S328N | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100579555; called by muse, mutect2, varscan2
- ABCC12 | c.1362G>T p.K454N | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV60911926, COSV60913332; called by muse, mutect2, varscan2
- ABCC3 | c.1921C>A p.P641T | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.312); catalogued as COSV99559153; called by muse, mutect2, varscan2
- ABCC4 | c.1503G>T p.K501N | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.77); catalogued as COSV65311926; called by muse, mutect2, varscan2
- ABCC6 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773604010, COSV52743253; called by muse, mutect2, varscan2
- ABCC8 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs577545383, COSV56849292; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCD2 | c.1660C>A p.L554I | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0.009); catalogued as COSV58051267, COSV58051917; called by muse, mutect2, varscan2
- ABCD2 | c.1311T>G p.I437M | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.438); catalogued as COSV58051277; called by muse, varscan2
- ABCD3 | c.584A>C p.K195T | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV59865905; called by muse, mutect2, varscan2
- ABCF2 | c.920C>T p.T307M | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.418); catalogued as rs753104612, COSV55181563; called by muse, mutect2, varscan2
- ABCF3 | c.206A>G p.Y69C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.379); catalogued as rs377432816; called by muse, mutect2, varscan2
- ABCF3 | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 21/93 reads (23%) | catalogued as rs1339124014, COSV53047738; called by muse, mutect2, varscan2
- ABCG4 | c.739G>T p.A247S | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.791); catalogued as COSV56643286; called by muse, mutect2, varscan2
- ABCG5 | c.1649+1G>A p.X550_splice | Splice Site (SNP) | VAF 35/87 reads (40%) | catalogued as COSV53210428; called by muse, mutect2, varscan2
- ABHD5 | c.188T>C p.I63T | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV50006477; called by muse, varscan2
- ABHD5 | c.204C>A p.F68L | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.92); PolyPhen benign (0.005); catalogued as COSV50006482; called by muse, varscan2
- ABHD6 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as COSV55908395; called by muse, mutect2, varscan2
- ABI3 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs200803220, COSV56799265; called by muse, mutect2, varscan2
- ABI3BP | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.396); catalogued as COSV52526696; called by muse, varscan2
- ABITRAM | c.88G>T p.G30* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100534617; called by muse, mutect2, varscan2
- ABL2 | c.929A>G p.Y310C (on ENST00000502732 / NM_007314.4; = p.Y295C on NM_005158.5) | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV61013006; called by muse, mutect2, varscan2
- ABLIM2 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1315520248, COSV56408122; called by muse, mutect2, varscan2
- ABR | c.2207G>A p.R736Q (on ENST00000302538 / NM_021962.5; = p.R699Q on NM_001092.5) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as rs200228390, COSV52144690; called by muse, mutect2, varscan2
- ABR | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as rs764110029, COSV100215288; called by muse, mutect2, varscan2
- ABRAXAS2 | c.776G>T p.R259I | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV53716687; called by muse, mutect2, varscan2
- ABRAXAS2 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV53716696; called by muse, mutect2, varscan2
- ABT1 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 45/128 reads (35%) | catalogued as COSV51291052; called by muse, mutect2, varscan2
- AC013477.1 | c.2483G>A p.R828Q | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.14); catalogued as rs748702473, COSV53653590; called by muse, mutect2, varscan2
- AC024598.1 | c.1006C>A p.L336I | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV67921869; called by muse, mutect2, varscan2
- AC097636.1 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371775341; called by muse, mutect2, varscan2
- AC100868.1 | c.1970A>G p.D657G | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.391); catalogued as COSV51841385; called by muse, mutect2, varscan2
- AC134980.2 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs762958062, COSV100171425, COSV60906951; called by mutect2, varscan2
- ACAD11 | c.899C>A p.S300Y | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (1); PolyPhen possibly damaging (0.481); catalogued as rs1347523848, COSV53895502; called by muse, mutect2, varscan2
- ACAD8 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs142790411; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACAN | c.2036C>T p.A679V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs367992413; called by muse, mutect2, varscan2
- ACAP1 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs756716611, COSV50135201; called by mutect2, varscan2
- ACCSL | c.785T>C p.V262A | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV101122198; called by muse, varscan2
- ACE | c.2708C>T p.S903L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs558504919, COSV52005823; called by muse, mutect2, varscan2
- ACER2 | c.73A>G p.T25A | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.88); PolyPhen benign (0.005); catalogued as rs767197220, COSV100575809; called by mutect2, varscan2
- ACHE | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as rs374462106; called by muse, mutect2, varscan2
- ACOT6 | c.476C>A p.S159Y | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV66968922; called by muse, mutect2, varscan2
- ACP5 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.382); catalogued as rs756201795, COSV99520328; called by mutect2, varscan2
- ACSBG2 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as COSV53124179; called by muse, mutect2, varscan2
- ACSL4 | c.1574A>C p.N525T (on ENST00000340800 / NM_022977.2; = p.N484T on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/123 reads (68%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.938); catalogued as COSV61614057; called by muse, mutect2, varscan2
- ACSM2B | c.1351G>T p.D451Y | Missense Mutation (SNP) | VAF 57/233 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61657538; called by muse, varscan2
- ACSM2B | c.305G>A p.G102D | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as COSV61657542; called by muse, mutect2, varscan2
- ACSM5 | c.1125+2T>C p.X375_splice | Splice Site (SNP) | VAF 8/16 reads (50%) | catalogued as COSV100088918; called by mutect2, varscan2
- ACSS2 | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs754546126, COSV99489865; called by muse, mutect2, varscan2
- ACSS3 | c.645G>T p.K215N | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV54089515; called by muse, varscan2
- ACTG2 | c.182G>T p.S61I | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.805); catalogued as COSV61828147; called by muse, mutect2, varscan2
- ACTL8 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as rs201038955, COSV64861125; called by muse, mutect2, varscan2
- ACTN2 | c.1211A>C p.E404A | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV100856805, COSV63978596; called by muse, mutect2, varscan2
- ACTN3 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1232811519, COSV72207678; called by muse, mutect2, varscan2
- ACTN3 | c.1139A>C p.N380T | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as COSV101557836; called by muse, mutect2, varscan2
- ACTR10 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as rs554639681, COSV54298006; called by muse, mutect2, varscan2
- ADAM11 | c.2005G>A p.A669T | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV52345659; called by muse, mutect2, varscan2
- ADAM12 | c.767A>G p.N256S | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV64105313; called by muse, mutect2, varscan2
- ADAM18 | c.2186C>T p.S729F | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs868150827, COSV55846395; called by muse, varscan2
- ADAM2 | c.983A>C p.K328T | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV55861170; called by muse, mutect2, varscan2
- ADAM21 | c.1204G>T p.E402* | Nonsense Mutation (SNP) | VAF 29/65 reads (45%) | catalogued as COSV50791466; called by muse, mutect2, varscan2
- ADAM21 | c.2155C>A p.H719N | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV99961013; called by muse, mutect2, varscan2
- ADAM23 | c.394C>A p.L132I | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52212968; called by muse, mutect2, varscan2
- ADAM23 | c.2011A>G p.I671V | Missense Mutation (SNP) | VAF 65/200 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as COSV52212996; called by muse, mutect2, varscan2
- ADAM32 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as rs567675296, COSV65946823; called by muse, mutect2, varscan2
- ADAM7 | c.1465G>T p.G489* | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | catalogued as COSV51538649; called by muse, mutect2, varscan2
- ADAM7 | c.2192A>C p.E731A | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV51538684; called by muse, mutect2, varscan2
- ADAM8 | c.2003T>C p.V668A | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.03); catalogued as COSV101291668; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1027A>G p.N343D | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.062); catalogued as COSV56474977; called by muse, mutect2, varscan2
- ADAMTS1 | c.2156G>T p.G719V | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1201501007, COSV99536126, COSV99536646; called by muse, mutect2, varscan2
- ADAMTS1 | c.1648G>A p.D550N | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as rs1204150067, COSV53168846; called by muse, mutect2, varscan2
- ADAMTS10 | c.2617C>T p.P873S | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.682); catalogued as COSV54353893; called by muse, mutect2, varscan2
- ADAMTS12 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV61261019; called by muse, varscan2
- ADAMTS13 | c.3250T>C p.C1084R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52472032, COSV99390273; called by muse, mutect2, varscan2
- ADAMTS13 | c.4234G>A p.V1412I | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.017); catalogued as COSV52469623; called by muse, mutect2, varscan2
- ADAMTS16 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760889068, COSV56984347; called by muse, mutect2, varscan2
- ADAMTS16 | c.1686T>G p.I562M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99941178; called by muse, mutect2, varscan2
- ADAMTS16 | c.2318G>T p.S773I | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV56986062; called by muse, mutect2, varscan2
- ADAMTS16 | c.2478G>T p.E826D | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56976773, COSV56980243; called by muse, mutect2, varscan2
- ADAMTS17 | c.2377G>A p.E793K | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.709); catalogued as rs139385294; called by muse, mutect2, varscan2
- ADAMTS18 | c.2468G>A p.R823H | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs189744529, COSV51401748; called by muse, mutect2, varscan2
- ADAMTS18 | c.1687G>A p.G563R | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51405347; called by muse, mutect2, varscan2
- ADAMTS19 | c.1189C>T p.H397Y | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV50742786; called by muse, mutect2, varscan2
- ADAMTS19 | c.1991G>A p.R664H | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs373980646, COSV50756015; called by muse, varscan2
- ADAMTS19 | c.2333C>A p.S778Y | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50742963; called by muse, mutect2, varscan2
- ADAMTS2 | c.1587G>T p.K529N | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51075894; called by muse, mutect2, varscan2
- ADAMTS20 | c.4415T>C p.V1472A | Missense Mutation (SNP) | VAF 69/189 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV67130276; called by muse, mutect2, varscan2
- ADAMTS20 | c.3217G>T p.E1073* | Nonsense Mutation (SNP) | VAF 29/81 reads (36%) | catalogued as COSV67137994, COSV67138012; called by muse, mutect2, varscan2
- ADAMTS3 | c.3467T>C p.V1156A | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV99711075; called by muse, varscan2
- ADAMTS3 | c.2152A>G p.T718A | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs760660569, COSV54389664; called by muse, mutect2, varscan2
- ADAMTS3 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750800733, COSV54388911; called by muse, mutect2, varscan2
- ADAMTS4 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs1343826431, COSV63487304, COSV63488443; called by muse, mutect2, varscan2
- ADAMTS6 | c.2810C>T p.T937M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1373514195, COSV58681557; called by muse, mutect2, varscan2
- ADAMTS6 | c.1993C>T p.R665C | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV66859012; called by muse, varscan2
- ADAMTS6 | c.1952C>T p.A651V | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV66859015; called by muse, varscan2
- ADAMTS6 | c.808G>T p.D270Y | Missense Mutation (SNP) | VAF 63/199 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66858399, COSV66861656; called by muse, varscan2
- ADAMTS9 | c.3253C>T p.R1085* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as COSV55781645; called by muse, mutect2, varscan2
- ADAMTS9 | c.2699G>A p.R900Q | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as rs766944266, COSV55777384; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1286C>T p.A429V | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs747562381, COSV52808351; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2220T>C p.C740= | Splice Region (SNP) | VAF 9/32 reads (28%) | catalogued as COSV65891597; called by muse, mutect2, varscan2
- ADAMTSL2 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1268212985, COSV63203828; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201221517; called by muse, mutect2, varscan2
- ADAP2 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs771539682, COSV58295708; called by muse, mutect2, varscan2
- ADAP2 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV58295717; called by muse, mutect2, varscan2
- ADARB1 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as COSV100653833; called by muse, mutect2, varscan2
- ADCK1 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as COSV53080062; called by muse, mutect2, varscan2
- ADCY1 | c.3022C>T p.R1008W | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52030467; called by muse, mutect2, varscan2
- ADCY3 | c.857A>C p.H286P | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99568252; called by muse, mutect2, varscan2
- ADCY4 | c.3203G>A p.R1068Q | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as rs1378408153, COSV60253710; called by muse, mutect2, varscan2
- ADCY4 | c.464T>C p.V155A | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs542980474, COSV53476956; called by muse, mutect2, varscan2
- ADCY6 | c.3087G>T p.K1029N | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57167494; called by muse, varscan2
- ADCY8 | c.3703G>A p.G1235S | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.023); catalogued as rs980635131, COSV53899685; called by muse, mutect2, varscan2
- ADCY8 | c.2009G>A p.R670K | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.542); catalogued as COSV53904640; called by muse, mutect2, varscan2
- ADCY9 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as COSV53573911, COSV53581701; called by muse, mutect2, varscan2
- ADCY9 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as COSV53574790; called by muse, mutect2, varscan2
- ADD2 | c.991C>A p.L331I | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.061); catalogued as COSV52459598, COSV52471371; called by muse, mutect2, varscan2
- ADD3 | c.407T>G p.L136R | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV53321786; called by muse, mutect2, varscan2
- ADGRA1 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs373898149; called by muse, mutect2, varscan2
- ADGRA3 | c.1325G>A p.R442Q | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.838); catalogued as rs758044902, COSV51562315; called by muse, mutect2, varscan2
- ADGRB1 | c.4417C>T p.R1473W | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs961477011, COSV60091791; called by muse, mutect2, varscan2
- ADGRB2 | c.3494C>T p.A1165V | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1161827683, COSV57070868; called by muse, varscan2
- ADGRB2 | c.2188C>T p.P730S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57072818; called by muse, mutect2, varscan2
- ADGRE2 | c.19C>A p.L7I | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV59693012; called by muse, mutect2, varscan2
- ADGRF1 | c.2452G>A p.A818T | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as COSV51944954; called by muse, mutect2, varscan2
- ADGRF1 | c.572G>T p.R191I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.403); catalogued as rs753292636, COSV51944555, COSV51946042; called by mutect2, varscan2
- ADGRF5 | c.325A>G p.T109A | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV51932749; called by muse, mutect2, varscan2
- ADGRF5 | c.28T>C p.C10R | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as COSV51932761; called by muse, mutect2, varscan2
- ADGRG3 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149674334; called by muse, mutect2, varscan2
- ADGRG4 | c.4393T>C p.S1465P | Missense Mutation (SNP) | VAF 45/72 reads (63%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV54954243; called by muse, mutect2, varscan2
- ADGRG6 | c.2312C>T p.A771V | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1246600532, COSV99747177; called by muse, mutect2, varscan2
- ADGRL2 | c.3118G>A p.A1040T (on ENST00000370717 / NM_001366005.1; = p.A1027T on NM_012302.4) | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1470284505, COSV54663803, COSV54665192; called by muse, mutect2, varscan2
- ADGRL3 | c.3002G>A p.R1001Q (on ENST00000506720 / NM_001322402.2; = p.R933Q on NM_015236.6) | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.888); catalogued as rs370040630; called by muse, mutect2
- ADGRL4 | c.1987T>G p.F663V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV66061153; called by muse, mutect2, varscan2
- ADGRL4 | c.1513T>C p.F505L | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66061158; called by muse, mutect2, varscan2
- ADGRV1 | c.7370C>A p.A2457D | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as COSV101315269, COSV67983572; called by muse, mutect2, varscan2
- ADGRV1 | c.13465A>G p.T4489A | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1487028244, COSV101315973; called by muse, mutect2
- ADGRV1 | c.15267T>G p.F5089L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as COSV67983577; called by muse, mutect2, varscan2
- ADH1B | c.18+1G>T p.X6_splice | Splice Site (SNP) | VAF 44/131 reads (34%) | catalogued as COSV100520861, COSV59296020; called by muse, mutect2, varscan2
- ADH5 | c.328C>A p.L110I | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as COSV56447977; called by muse, mutect2, varscan2
- ADH6 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs61755961, COSV52955791; called by muse, varscan2
- ADH6 | c.483T>G p.I161M | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV52955906; called by muse, varscan2
- ADH7 | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs760167786, COSV99265256; called by muse, mutect2, varscan2
- ADH7 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs147020637; called by muse, mutect2, varscan2
- ADIPOQ | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57858957; called by muse, mutect2, varscan2
- ADIPOQ | c.427T>G p.Y143D | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57858968; called by muse, mutect2, varscan2
- ADIPOR2 | c.446T>C p.I149T | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63946115; called by muse, mutect2, varscan2
- ADK | c.226G>A p.E76K (on ENST00000286621; = p.E59K on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs1473972097, COSV54204007; called by muse, mutect2, varscan2
- ADNP2 | c.1036A>G p.T346A | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100080876; called by muse, mutect2, varscan2
- ADORA1 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.747); catalogued as rs778641521, COSV55142136, COSV99704669; called by muse, mutect2, varscan2
- ADRA1D | c.1151T>C p.F384S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.144); catalogued as COSV101063004; called by muse, mutect2, varscan2
- AEBP1 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs779044302, COSV99788780; called by muse, mutect2, varscan2
- AEBP2 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.98); catalogued as COSV56863122; called by muse, mutect2, varscan2
- AFAP1 | c.2150T>C p.V717A | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61795077; called by muse, mutect2, varscan2
- AFDN | c.756T>G p.I252M | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV60043018; called by muse, mutect2, varscan2
- AFF3 | c.2909T>C p.F970S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV57851443; called by muse, mutect2, varscan2
- AFF4 | c.3204T>G p.N1068K | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs1182504792, COSV54793975; called by muse, mutect2, varscan2
- AGAP2 | c.2218C>T p.P740S (on ENST00000547588 / NM_001122772.2; = p.P404S on NM_014770.4) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99223166; called by muse, mutect2, varscan2
- AGBL1 | c.2062A>C p.I688L | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV66855663; called by muse, mutect2, varscan2
- AGBL2 | c.2400G>T p.E800D | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.257); catalogued as COSV54091418; called by muse, varscan2
- AGFG1 | c.1410G>T p.M470I | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV100028771; called by muse, mutect2, varscan2
- AGGF1 | c.1702A>C p.K568Q | Missense Mutation (SNP) | VAF 136/443 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57228664; called by muse, mutect2, varscan2
- AGL | c.1130G>T p.R377I | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV54051702; called by muse, mutect2, varscan2
- AGO1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs371043471; called by muse, mutect2, varscan2
- AGO4 | c.1489T>C p.F497L | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as COSV64616970; called by muse, mutect2, varscan2
- AGPAT4 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV57245187; called by muse, mutect2, varscan2
- AGT | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as rs374540090, COSV64184402; called by muse, varscan2
- AGT | c.122T>C p.F41S | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100794348; called by muse, varscan2
- AGTPBP1 | c.548T>C p.L183S | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV61270772; called by muse, mutect2, varscan2
- AHCTF1 | c.604C>A p.L202I (on ENST00000366508; = p.L176I on NM_015446.5) | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58248840; called by muse, mutect2, varscan2
- AHDC1 | c.1622T>G p.I541S | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV55938184; called by muse, mutect2, varscan2
- AHR | c.1172G>T p.G391V | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99619707; called by muse, mutect2, varscan2
- AHRR | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as rs773041292, COSV57085012, COSV57093294; called by muse, mutect2, varscan2
- AIDA | c.431C>A p.S144Y | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV60663636; called by muse, mutect2, varscan2
- AIM2 | c.931C>T p.R311* | Nonsense Mutation (SNP) | VAF 64/192 reads (33%) | catalogued as rs145420527; called by muse, mutect2, varscan2
- AIM2 | c.113G>A p.G38D | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.83); PolyPhen benign (0.355); catalogued as COSV63699180; called by muse, mutect2, varscan2
- AIRE | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs778067704, COSV52392624; called by muse, mutect2, varscan2
- AJAP1 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65452005; called by muse, mutect2, varscan2
- AK9 | c.293T>C p.M98T | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs1455135944, COSV99572523; called by muse, varscan2
- AKAP12 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs149211517; called by muse, mutect2, varscan2
- AKAP12 | c.2200G>T p.E734* | Nonsense Mutation (SNP) | VAF 21/74 reads (28%) | catalogued as COSV53573594; called by muse, mutect2, varscan2
- AKAP12 | c.4708G>A p.E1570K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as rs1432203514, COSV53573622; called by muse, mutect2, varscan2
- AKAP13 | c.2686A>T p.S896C | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV63454454; called by muse, mutect2, varscan2
- AKAP14 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT tolerated (0.17); PolyPhen benign (0.127); catalogued as rs1433845368, COSV57629901; called by muse, mutect2, varscan2
- AKAP3 | c.2072C>T p.S691L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as rs145618639, COSV57415831; called by mutect2, varscan2
- AKAP6 | c.5632A>G p.N1878D | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.395); catalogued as COSV99800833; called by muse, mutect2, varscan2
- AKAP9 | c.3021A>C p.E1007D | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.65); catalogued as COSV62343945; called by muse, mutect2, varscan2
- AKAP9 | c.5150T>C p.L1717S | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as rs1358778741, COSV100662401; called by muse, mutect2, varscan2
- AKNAD1 | c.1189G>T p.E397* | Nonsense Mutation (SNP) | VAF 14/76 reads (18%) | catalogued as COSV62197610; called by muse, mutect2, varscan2
- AKR1B10 | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.033); catalogued as rs563438026, COSV62055323; called by muse, mutect2
- AKR1B15 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 31/81 reads (38%) | catalogued as COSV71151618; called by muse, mutect2, varscan2
- AKT3 | c.1057A>C p.K353Q | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.191); catalogued as COSV99795384; called by muse, mutect2, varscan2
- AL358113.1 | c.3296G>A p.R1099Q | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.105); catalogued as rs150494393; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AL592490.1 | c.1793A>G p.D598G | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69425801; called by muse, mutect2, varscan2
- ALDH16A1 | c.1382C>T p.S461L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs768690823, COSV53193518; called by muse, mutect2, varscan2
- ALDH1L2 | c.793A>G p.T265A | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.158); catalogued as COSV99311038; called by muse, mutect2
- ALDH5A1 | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV62373297; called by muse, mutect2, varscan2
- ALG10 | c.1164G>T p.L388F | Missense Mutation (SNP) | VAF 85/252 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as COSV56792256; called by muse, mutect2, varscan2
- ALG11 | c.1106A>G p.Y369C | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as rs77859426, COSV73000635; called by muse, mutect2, varscan2
- ALG13 | c.1987C>T p.R663W | Missense Mutation (SNP) | VAF 57/88 reads (65%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs759862252, COSV52637951; called by muse, mutect2, varscan2
- ALG14 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.687); catalogued as rs767036165, COSV64634688; called by muse, mutect2, varscan2
- ALG8 | c.1054C>A p.L352I | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.576); catalogued as COSV55200069; called by mutect2, varscan2
- ALG8 | c.210C>A p.F70L | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.034); catalogued as COSV55200094; called by muse, mutect2, varscan2
- ALKBH5 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.212); catalogued as rs751699434, COSV67686932; called by muse, mutect2, varscan2
- ALKBH6 | c.203G>A p.R68Q (on ENST00000252984 / NM_001297701.2; = p.R96Q on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as rs1274474050, COSV99431054, COSV99431236; called by muse, mutect2, varscan2
- ALMS1 | c.8860G>A p.D2954N | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.584); catalogued as COSV52508135; called by muse, mutect2, varscan2
- ALOX5 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs148401371; called by muse, mutect2, varscan2
- ALOXE3 | c.832T>C p.Y278H | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs758981995, COSV59075234; called by muse, mutect2, varscan2
- ALS2CL | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as rs138555173, COSV59671044; called by muse, mutect2, varscan2
- AMBRA1 | c.2335T>G p.F779V (on ENST00000458649 / NM_001367468.1; = p.F689V on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.086); catalogued as COSV54052619; called by muse, mutect2, varscan2
- AMER1 | c.2824C>T p.R942* | Nonsense Mutation (SNP) | VAF 45/68 reads (66%) | catalogued as rs1404477878, COSV57657623; called by muse, mutect2, varscan2
- AMER1 | c.1979G>A p.G660D | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV57659396; called by muse, mutect2, varscan2
- AMMECR1L | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as COSV55760188, COSV99761263; called by muse, mutect2, varscan2
- AMOT | c.2075G>A p.R692K (on ENST00000371959 / NM_001113490.1; = p.R283K on NM_133265.3) | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59062701; called by muse, mutect2, varscan2
- AMOT | c.1630+2T>C p.X544_splice (on ENST00000371959 / NM_001113490.1; = p.X135_splice on NM_133265.3) | Splice Site (SNP) | VAF 19/32 reads (59%) | catalogued as COSV59062726; called by muse, mutect2, varscan2
- AMOTL1 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV100133787; called by muse, mutect2, varscan2
- AMOTL1 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV58566090; called by muse, mutect2, varscan2
- AMOTL1 | c.2650G>A p.E884K | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as rs771639549, COSV58566105; called by muse, mutect2, varscan2
- AMPD1 | c.706A>C p.N236H | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV100815033; called by muse, mutect2, varscan2
- AMPD3 | c.198G>T p.Q66H (on ENST00000396553 / NM_001025389.2; = p.Q75H on NM_000480.3) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.593); catalogued as COSV67330655; called by muse, mutect2, varscan2
- AMPD3 | c.1193C>T p.A398V (on ENST00000396553 / NM_001025389.2; = p.A407V on NM_000480.3) | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.974); catalogued as COSV67330660; called by muse, mutect2, varscan2
- AMPH | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV57739926; called by muse, mutect2, varscan2
- AMPH | c.1135A>G p.T379A | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV57733127, COSV57755178; called by muse, mutect2, varscan2
- AMPH | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 31/103 reads (30%) | catalogued as rs771517892, COSV57739938; called by muse, mutect2, varscan2
- AMY2B | c.1355C>A p.S452Y | Missense Mutation (SNP) | VAF 115/435 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as rs766587051, COSV63714875; called by muse, mutect2, varscan2
- ANAPC1 | c.5777G>A p.R1926Q | Missense Mutation (SNP) | VAF 53/207 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as COSV100594728; called by muse, mutect2, varscan2
- ANAPC2 | c.1222C>A p.R408S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV60569629; called by muse, mutect2, varscan2
- ANAPC5 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.532); catalogued as COSV55841832, COSV55842606; called by muse, mutect2, varscan2
- ANGPT4 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1365799158, COSV67921336; called by muse, varscan2
- ANGPT4 | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67921340; called by muse, varscan2
- ANGPTL1 | c.141G>T p.K47N | Missense Mutation (SNP) | VAF 94/298 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.15); catalogued as COSV52366100; called by muse, mutect2, varscan2
- ANGPTL2 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs367678181; called by muse, mutect2, varscan2
- ANK1 | c.4601C>T p.P1534L | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.133); catalogued as rs755323122, COSV55879482; called by muse, mutect2, varscan2
- ANK1 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs141945303, COSV55889933; called by muse, mutect2, varscan2
- ANK2 | c.3007C>T p.R1003* | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | catalogued as COSV52156986; called by muse, mutect2, varscan2
- ANK2 | c.4407C>T p.I1469= | Splice Region (SNP) | VAF 11/45 reads (24%) | catalogued as rs1355288561, COSV100004933, COSV52153997; called by muse, mutect2, varscan2
- ANK3 | c.11381C>A p.S3794Y | Missense Mutation (SNP) | VAF 94/258 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); catalogued as COSV55054127; called by muse, mutect2, varscan2
- ANK3 | c.6893C>T p.S2298L | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV99779427; called by muse, mutect2, varscan2
- ANK3 | c.2248C>A p.L750I | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as COSV55054135; called by muse, mutect2, varscan2
- ANK3 | c.43G>T p.E15* | Nonsense Mutation (SNP) | VAF 77/233 reads (33%) | catalogued as COSV55054155, COSV55076599; called by muse, mutect2, varscan2
- ANKEF1 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV65692161, COSV65692420; called by muse, mutect2, varscan2
- ANKFN1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.971); catalogued as COSV59445646; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6425C>A p.S2142Y | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.556); catalogued as COSV51845377; called by muse, mutect2, varscan2
- ANKIB1 | c.498A>C p.K166N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.029); catalogued as COSV56060670; called by muse, mutect2, varscan2
- ANKK1 | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 26/69 reads (38%) | catalogued as COSV58271435; called by muse, mutect2, varscan2
- ANKRD10 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779123844, COSV57442692; called by muse, mutect2, varscan2
- ANKRD11 | c.7123G>A p.E2375K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1219555844, COSV99969323; called by muse, mutect2
- ANKRD12 | c.3922C>T p.R1308* | Nonsense Mutation (SNP) | VAF 36/115 reads (31%) | catalogued as rs766734820, COSV50819104; called by muse, mutect2, varscan2
- ANKRD13A | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs769790065, COSV55676043; called by muse, mutect2, varscan2
- ANKRD13C | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as rs1461634372, COSV52030719; called by muse, mutect2, varscan2
- ANKRD17 | c.2684G>T p.R895I | Missense Mutation (SNP) | VAF 100/329 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.497); catalogued as COSV58216151; called by muse, mutect2, varscan2
- ANKRD23 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV100450428; called by muse, mutect2, varscan2
- ANKRD24 | c.2056G>T p.G686* | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | catalogued as COSV53669692; called by muse, mutect2, varscan2
- ANKRD26 | c.4623A>C p.K1541N | Missense Mutation (SNP) | VAF 77/237 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV65775055; called by muse, mutect2, varscan2
- ANKRD28 | c.2203C>A p.L735I | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV67519020; called by muse, varscan2
- ANKRD28 | c.2143C>T p.R715W | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs202220330; called by muse, varscan2
- ANKRD30A | c.2503A>C p.K835Q (on ENST00000611781; = p.K779Q on NM_052997.2) | Missense Mutation (SNP) | VAF 86/292 reads (29%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.775); catalogued as COSV100653535; called by muse, varscan2
- ANKRD30A | c.2527G>A p.D843N (on ENST00000611781; = p.D787N on NM_052997.2) | Missense Mutation (SNP) | VAF 90/315 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.043); catalogued as COSV64608669; called by muse, varscan2
- ANKRD30A | c.3006A>T p.K1002N (on ENST00000611781; = p.K946N on NM_052997.2) | Missense Mutation (SNP) | VAF 20/410 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV100653536; called by muse, mutect2
- ANKRD35 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.056); catalogued as rs141824672; called by muse, mutect2, varscan2
- ANKRD44 | c.2188C>A p.L730I | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.15); catalogued as COSV56553709; called by muse, mutect2, varscan2
- ANKRD45 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.353); catalogued as rs754680825, COSV60960807; called by muse, mutect2, varscan2
- ANO3 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs754306957, COSV56785250, COSV56806565; called by mutect2, varscan2
- ANO3 | c.2240A>G p.N747S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); catalogued as COSV99882858; called by muse, varscan2
- ANO4 | c.2591C>T p.P864L (on ENST00000392977 / NM_001286615.2; = p.P829L on NM_178826.4) | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs536770439, COSV54593222; called by muse, mutect2, varscan2
- ANO5 | c.145A>G p.K49E | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV100201854; called by muse, varscan2
- ANO5 | c.1925G>A p.R642Q | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as rs199532484, CM137911, COSV61084245; called by muse, mutect2, varscan2
- ANO6 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.011); catalogued as COSV57660093; called by muse, mutect2, varscan2
- ANO6 | c.1108T>G p.L370V | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.205); catalogued as COSV57660118; called by muse, mutect2, varscan2
- ANO7 | c.2694+1G>A p.X898_splice (on ENST00000274979; = p.X844_splice on NM_001370694.2) | Splice Site (SNP) | VAF 27/92 reads (29%) | catalogued as rs1364192116, COSV51470942; called by muse, mutect2, varscan2
- ANTXR1 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1173410150, COSV58010783; called by muse, mutect2, varscan2
- ANXA11 | c.745-1G>A p.X249_splice | Splice Site (SNP) | VAF 14/44 reads (32%) | catalogued as COSV99627150; called by muse, mutect2, varscan2
- ANXA3 | c.591C>A p.F197L | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV53714200; called by muse, mutect2, varscan2
- ANXA3 | c.799A>G p.T267A | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53714211; called by muse, mutect2, varscan2
- ANXA6 | c.1820A>C p.K607T | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.291); catalogued as COSV62906389; called by muse, mutect2, varscan2
- ANXA9 | c.162T>G p.I54M | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV64484659; called by muse, mutect2, varscan2
- AP001781.2 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as COSV52788112, COSV99500304; called by muse, mutect2, varscan2
- AP1B1 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58014197; called by muse, mutect2, varscan2
- AP1G1 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs770148749, COSV55488248; called by muse, mutect2, varscan2
- AP1S1 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs754050754, COSV61760409; called by muse, mutect2, varscan2
- AP2A2 | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 46/139 reads (33%) | catalogued as COSV59959842; called by muse, varscan2
- AP2B1 | c.146C>A p.S49Y | Missense Mutation (SNP) | VAF 85/249 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV51998261; called by muse, mutect2, varscan2
- AP2B1 | c.1272G>A p.K424= | Splice Region (SNP) | VAF 12/50 reads (24%) | catalogued as COSV99251255; called by muse, mutect2, varscan2
- AP4M1 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1048686470, COSV100384905; called by muse, mutect2, varscan2
- APBB1 | c.1958C>T p.A653V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54967686; called by muse, mutect2
- APC | c.1772C>T p.A591V | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99967850; called by muse, mutect2, varscan2
- APC | c.3581C>A p.S1194* | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | catalogued as CM040004, CM970088, COSV57339248; called by muse, mutect2, varscan2
- APC | c.6920C>T p.S2307L | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs901983934, COSV57330138; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APCDD1 | c.1372T>C p.S458P | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1222539514, COSV62372369; called by muse, mutect2, varscan2
- APH1B | c.145T>C p.S49P | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV56014156; called by muse, mutect2, varscan2
- APH1B | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 17/80 reads (21%) | catalogued as rs200231201, COSV99971536; called by muse, mutect2, varscan2
- APLF | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV58144196; called by muse, mutect2, varscan2
- APLP1 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.941); catalogued as rs568306221, COSV55702927; called by muse, varscan2
- APOB | c.9358G>T p.E3120* | Nonsense Mutation (SNP) | VAF 34/134 reads (25%) | catalogued as COSV99264350; called by muse, mutect2, varscan2
- APOBEC2 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.92); PolyPhen benign (0.321); catalogued as rs1065197, COSV99775374; called by muse, mutect2, varscan2
- APOBEC3B | c.897G>T p.E299D | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.22); PolyPhen benign (0.097); catalogued as COSV100213769; called by muse, mutect2, varscan2
- APOBEC3C | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.791); catalogued as rs367840996, COSV100815161; called by muse, varscan2
- APOBEC3C | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1052963574, COSV63865247; called by muse, varscan2
- APOBEC3C | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53326357; called by muse, mutect2, varscan2
- APOD | c.153G>T p.K51N | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58401876; called by muse, mutect2, varscan2
- APOH | c.856T>A p.F286I | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.255); catalogued as COSV52772237; called by muse, mutect2, varscan2
- APOH | c.686A>C p.K229T | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV52772250; called by muse, mutect2, varscan2
- APOL6 | c.216G>T p.K72N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1269270139, COSV68749462; called by muse, mutect2, varscan2
- APPBP2 | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV50026453; called by muse, mutect2, varscan2
- APPL1 | c.1376C>A p.S459Y | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as COSV55700394, COSV99897345; called by muse, mutect2, varscan2
- APTX | c.533C>A p.P178H | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58928439; called by muse, mutect2, varscan2
- APTX | c.176A>C p.K59T | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV58928453; called by muse, mutect2, varscan2
- AQP1 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (1); PolyPhen probably damaging (0.95); catalogued as rs898407370, COSV61266523; called by muse, mutect2, varscan2
- AQP9 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as rs192641731; called by muse, varscan2
- AQP9 | c.629A>G p.N210S | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV99582912; called by muse, mutect2, varscan2
- ARAP1 | c.1407G>T p.K469N (on ENST00000393609 / NM_001040118.2; = p.K224N on NM_015242.4) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61990819; called by muse, mutect2, varscan2
- ARAP2 | c.4613A>C p.E1538A | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV58285699; called by muse, mutect2, varscan2
- ARAP2 | c.4488G>T p.K1496N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58285709; called by muse, mutect2, varscan2
- ARAP2 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 24/62 reads (39%) | catalogued as COSV58282405; called by muse, mutect2, varscan2
- ARAP3 | c.3992T>C p.V1331A | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.6); catalogued as COSV53350140; called by muse, mutect2, varscan2
- AREL1 | c.1984T>G p.L662V | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.908); catalogued as COSV62666191; called by muse, mutect2, varscan2
- ARF4 | c.283A>G p.N95D | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.604); catalogued as COSV57714908; called by muse, mutect2, varscan2
- ARFGAP3 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as rs756482945, COSV54311590; called by muse, mutect2, varscan2
- ARFGEF3 | c.1918G>T p.E640* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as COSV99293490; called by muse, mutect2, varscan2
- ARFIP1 | c.1024G>A p.A342T (on ENST00000353617 / NM_001287432.1; = p.A310T on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.96); catalogued as COSV61884182; called by muse, mutect2, varscan2
- ARHGAP12 | c.2393G>A p.R798Q | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs998892661, COSV60962762; called by muse, mutect2, varscan2
- ARHGAP15 | c.8A>C p.K3T | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV54491943; called by muse, mutect2, varscan2
- ARHGAP18 | c.1135G>T p.E379* | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | catalogued as COSV63764213, COSV63766263; called by muse, mutect2, varscan2
- ARHGAP18 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as COSV63764221; called by muse, mutect2, varscan2
- ARHGAP19 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as COSV57392369, COSV57392530, COSV57393591; called by muse, mutect2, varscan2
- ARHGAP20 | c.3056A>G p.D1019G | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV52809814; called by muse, mutect2, varscan2
- ARHGAP20 | c.2125G>A p.D709N | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0.01); catalogued as rs368565272; called by muse, mutect2, varscan2
- ARHGAP20 | c.1007A>G p.N336S | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.872); catalogued as COSV52809249; called by muse, mutect2, varscan2
- ARHGAP21 | c.1949G>A p.R650K | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs1253916340, COSV100256219; called by muse, mutect2, varscan2
- ARHGAP21 | c.164G>T p.R55I | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64543164; called by muse, mutect2, varscan2
- ARHGAP25 | c.1116G>T p.K372N (on ENST00000409202 / NM_001007231.3; = p.K364N on NM_014882.3) | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV54901425; called by muse, mutect2, varscan2
- ARHGAP26 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.699); catalogued as rs368631485; called by muse, mutect2, varscan2
- ARHGAP31 | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 39/119 reads (33%) | catalogued as rs749661211, COSV51791883; called by muse, mutect2, varscan2
- ARHGAP31 | c.2951C>T p.S984F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV99956427, COSV99957110; called by muse, mutect2, varscan2
- ARHGAP35 | c.3440G>A p.R1147H | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV68330597; called by muse, mutect2, varscan2
- ARHGAP36 | c.1404G>T p.E468D | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV52265909; called by muse, mutect2, varscan2
- ARHGDIB | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.196); catalogued as rs774401441, COSV56763076; called by muse, mutect2, varscan2
- ARHGEF1 | c.1376A>G p.N459S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV100529005; called by muse, mutect2, varscan2
- ARHGEF10 | c.1514C>T p.S505L (on ENST00000398564; = p.S480L on NM_014629.4) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201240439, COSV50646851; called by muse, mutect2, varscan2
- ARHGEF12 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV63103349; called by muse, mutect2, varscan2
- ARHGEF15 | c.1811G>A p.R604H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs143720339; called by muse, mutect2, varscan2
- ARHGEF15 | c.2459G>A p.R820H | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs1431506674, COSV62724966, COSV62725153; called by muse, mutect2, varscan2
- ARHGEF17 | c.3986G>A p.R1329H | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs368051277; called by muse, mutect2, varscan2
- ARHGEF25 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as rs756197273, COSV54084640; called by muse, mutect2, varscan2
- ARHGEF25 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as rs1029273163, COSV54086047; called by muse, mutect2, varscan2
- ARHGEF26 | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs562212403, COSV62845684; called by muse, mutect2, varscan2
- ARHGEF3 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs764132102, COSV99575352; called by mutect2, varscan2
- ARHGEF6 | c.1236A>C p.K412N | Missense Mutation (SNP) | VAF 47/76 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51689638; called by muse, mutect2, varscan2
- ARID1A | c.2144C>T p.S715L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1387691435, COSV61375961; called by muse, mutect2, varscan2
- ARID1B | c.2108C>T p.A703V | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as rs774701560, COSV51653006; called by muse, mutect2, varscan2
- ARID1B | c.4101C>A p.Y1367* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as COSV99269138; called by muse, mutect2, varscan2
- ARID2 | c.881G>T p.R294I | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57599678, COSV57606673, COSV57614708; called by muse, mutect2, varscan2
- ARID2 | c.1616C>A p.S539Y | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs756281594, COSV57601886; called by muse, mutect2, varscan2
- ARID2 | c.3319G>A p.A1107T | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs529386166, COSV57601895; called by muse, mutect2, varscan2
- ARID4A | c.3069T>G p.S1023R | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV100794247; called by muse, mutect2, varscan2
- ARID5B | c.2606C>A p.S869Y | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.185); catalogued as rs201944744, COSV54415661; called by muse, mutect2, varscan2
- ARID5B | c.2842C>T p.R948* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV54418629, COSV99689059; called by muse, mutect2, varscan2
- ARL2 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs146832019; called by muse, mutect2, varscan2
- ARMC4 | c.521T>G p.L174R | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); catalogued as COSV53464425; called by muse, mutect2, varscan2
- ARNT2 | c.619A>T p.T207S | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.365); catalogued as COSV100309026; called by muse, mutect2, varscan2
- ARNTL | c.907G>A p.E303K (on ENST00000403290 / NM_001297719.2; = p.E302K on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs773491224, COSV100724712, COSV62986216; called by muse, mutect2, varscan2
- ARPP21 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51795890; called by muse, mutect2, varscan2
- ARPP21 | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 20/61 reads (33%) | catalogued as COSV51794552, COSV51810314; called by muse, mutect2, varscan2
- ARPP21 | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs374241256; called by mutect2, varscan2
- ARSG | c.614A>G p.E205G | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as COSV71593011; called by muse, mutect2, varscan2
- ART5 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 24/54 reads (44%) | catalogued as rs376288672; called by muse, mutect2, varscan2
- ARV1 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV59617615; called by muse, mutect2, varscan2
- ASAP2 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs757499704, COSV55635586; called by mutect2, varscan2
- ASB11 | c.175A>C p.I59L | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV60354415, COSV60354938; called by muse, mutect2, varscan2
- ASB15 | c.422dup p.N141Kfs*2 | Frame Shift Ins (INS) | VAF 26/100 reads (26%) | catalogued as rs1423358635; called by mutect2, pindel, varscan2
- ASB15 | c.1442T>G p.F481C | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51925476; called by muse, mutect2, varscan2
- ASB18 | c.1330A>G p.I444V | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as rs1158822454, COSV100430599; called by muse, mutect2
- ASB3 | c.122A>C p.N41T | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54857899; called by muse, mutect2, varscan2
- ASCC3 | c.4118C>A p.S1373* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as COSV64974379; called by muse, mutect2, varscan2
- ASCC3 | c.2849G>A p.R950Q | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.652); catalogued as rs373500478; called by muse, mutect2, varscan2
- ASGR2 | c.766T>C p.Y256H | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV54689980; called by muse, mutect2, varscan2
- ASH1L | c.6232C>T p.R2078C (on ENST00000368346 / NM_001366177.2; = p.R2073C on NM_018489.3) | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs772388982, COSV64204956; called by muse, mutect2, varscan2
- ASIC1 | c.1380C>A p.V460= | Splice Region (SNP) | VAF 26/63 reads (41%) | catalogued as COSV57317581; called by muse, mutect2, varscan2
- ASIC3 | c.820T>G p.F274V | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV52521559; called by muse, mutect2, varscan2
- ASIC4 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.57); catalogued as COSV61731568, COSV61731934; called by muse, mutect2, varscan2
- ASPA | c.336T>G p.I112M | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.763); catalogued as COSV53980921; called by muse, mutect2, varscan2
- ASPDH | c.662A>G p.D221G (on ENST00000389208 / NM_001114598.2; = p.D116G on NM_001024656.3) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV100975911; called by muse, mutect2, varscan2
- ASPG | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71933738; called by muse, mutect2, varscan2
- ASPM | c.8089T>C p.S2697P | Missense Mutation (SNP) | VAF 67/185 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV54128483; called by muse, mutect2, varscan2
- ASPM | c.7544G>A p.R2515Q | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs751584273, COSV54123850; called by muse, varscan2
- ASPM | c.6166G>A p.A2056T | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.543); catalogued as COSV54128509, COSV54133661; called by muse, mutect2, varscan2
- ASPM | c.1896G>T p.E632D | Missense Mutation (SNP) | VAF 84/217 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV54128518; called by muse, mutect2, varscan2
- ASTN1 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV56066791; called by muse, mutect2, varscan2
- ASXL1 | c.2674T>G p.S892A | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.024); catalogued as COSV60106654; called by muse, mutect2, varscan2
- ASXL2 | c.1964G>T p.R655I | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55457690; called by muse, mutect2, varscan2
- ASXL2 | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as COSV55456602; called by muse, mutect2, varscan2
- ASXL3 | c.1059C>A p.F353L | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52463579; called by muse, mutect2, varscan2
- ASXL3 | c.6242C>T p.S2081L | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.627); catalogued as rs200327794, COSV52463592; called by muse, mutect2, varscan2
- ATAD1 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV57756587; called by muse, mutect2, varscan2
- ATAD2 | c.1777G>T p.E593* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as COSV54879934; called by muse, mutect2, varscan2
- ATE1 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs749513221, COSV56433193; called by muse, mutect2, varscan2
- ATG9B | c.819G>T p.E273D | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV100939892; called by muse, mutect2, varscan2
- ATIC | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 28/106 reads (26%) | catalogued as rs200150457, COSV52695256; called by muse, mutect2, varscan2
- ATL1 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs1278783412, COSV63296335; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATL1 | c.1665G>T p.K555N | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.023); catalogued as COSV61204556; called by muse, mutect2, varscan2
- ATL2 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs780577030, COSV60051443, COSV60057060; called by muse, mutect2, varscan2
- ATM | c.662+2T>C p.X221_splice | Splice Site (SNP) | VAF 64/188 reads (34%) | catalogued as COSV53739297; called by muse, mutect2, varscan2
- ATM | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs750280306, COSV53739314; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATM | c.3741C>A p.F1247L | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV53725511; called by muse, mutect2, varscan2
- ATOH1 | c.527A>G p.N176S | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60037822; called by muse, mutect2, varscan2
- ATP10A | c.2149C>T p.R717W | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755196001, COSV63516408; called by muse, mutect2, varscan2
- ATP10A | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.427); catalogued as rs765464148, COSV63514303; called by mutect2, varscan2
- ATP10D | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754586853, COSV56706682; called by muse, mutect2, varscan2
- ATP11B | c.2646T>G p.F882L | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV60027910; called by muse, mutect2, varscan2
- ATP11C | c.2447C>T p.S816L | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV59562505, COSV59576393; called by muse, mutect2, varscan2
- ATP11C | c.2181G>T p.K727N | Missense Mutation (SNP) | VAF 51/78 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV59562556; called by muse, mutect2, varscan2
- ATP11C | c.1838G>T p.R613I | Missense Mutation (SNP) | VAF 69/93 reads (74%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs776753802, COSV59561860, COSV59563934; called by muse, mutect2, varscan2
- ATP13A3 | c.993G>T p.K331N | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV55463673; called by muse, mutect2, varscan2
- ATP13A3 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.063); catalogued as rs753872961, COSV55463686; called by muse, mutect2, varscan2
- ATP13A4 | c.2094G>T p.E698D | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as COSV61319252; called by muse, mutect2, varscan2
- ATP13A4 | c.494A>C p.K165T | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.206); catalogued as COSV55068521; called by muse, mutect2, varscan2
- ATP13A5 | c.1392G>T p.K464N | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.057); catalogued as COSV60868389; called by muse, mutect2, varscan2
- ATP13A5 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs776380026, COSV60868282; called by muse, mutect2, varscan2
- ATP1A2 | c.2230G>A p.D744N | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as rs1131691922, COSV63403458; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP1A4 | c.1994C>T p.A665V | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV63626264; called by muse, mutect2, varscan2
- ATP1B3 | c.752A>C p.K251T | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV53949539; called by muse, mutect2, varscan2
- ATP1B4 | c.357C>A p.F119L (on ENST00000218008 / NM_001142447.3; = p.F115L on NM_012069.5) | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV54312178; called by muse, mutect2, varscan2
- ATP2B3 | c.2384G>A p.G795D | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54844983; called by muse, mutect2, varscan2
- ATP2B4 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs141117629; called by muse, mutect2, varscan2
- ATP2C1 | c.360+2T>C p.X120_splice | Splice Site (SNP) | VAF 61/228 reads (27%) | catalogued as CS1210576, COSV60755451; called by muse, mutect2, varscan2
- ATP4B | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.904); catalogued as rs202021919; called by muse, mutect2, varscan2
- ATP5F1A | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs773771619, COSV56360242; called by muse, mutect2, varscan2
- ATP5MF-PTCD1 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.898); catalogued as rs11545970, COSV52854171; called by muse, mutect2, varscan2
- ATP6V0A1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746962618, COSV52872471; called by muse, mutect2, varscan2
- ATP6V0A1 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as COSV52872490; called by muse, mutect2, varscan2
- ATP6V0B | c.116+2T>C p.X39_splice | Splice Site (SNP) | VAF 22/50 reads (44%) | catalogued as COSV99356460; called by muse, mutect2, varscan2
- ATP6V1G2 | c.163T>G p.F55V | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV100385425; called by muse, mutect2, varscan2
- ATP7A | c.1642G>T p.E548* | Nonsense Mutation (SNP) | VAF 63/81 reads (78%) | catalogued as COSV58445162; called by muse, mutect2, varscan2
- ATP7B | c.353A>G p.D118G | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.131); catalogued as rs1352002305, COSV99666440; called by muse, mutect2, varscan2
- ATP8A2 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 37/112 reads (33%) | catalogued as rs759057352, COSV54947743; called by muse, mutect2, varscan2
- ATP8A2 | c.322-2A>G p.X108_splice | Splice Site (SNP) | VAF 27/61 reads (44%) | catalogued as COSV54947760; called by muse, mutect2, varscan2
- ATP9A | c.1101A>C p.K367N | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV58765405; called by muse, mutect2, varscan2
- ATP9B | c.2937C>A p.F979L | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV56949832; called by muse, mutect2, varscan2
- ATRN | c.1214A>G p.Y405C | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99497158; called by muse, mutect2, varscan2
- ATRNL1 | c.358A>G p.T120A | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61800338; called by muse, mutect2, varscan2
- ATRX | c.3392G>T p.R1131I | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.259); catalogued as COSV64872016, COSV64874765; called by muse, mutect2, varscan2
- ATXN7 | c.285G>A p.W95* | Nonsense Mutation (SNP) | VAF 26/77 reads (34%) | catalogued as COSV55750004; called by muse, mutect2, varscan2
- ATXN7 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.926); catalogued as rs751858038, COSV55750017; called by muse, mutect2, varscan2
- AXDND1 | c.994G>T p.E332* | Nonsense Mutation (SNP) | VAF 18/55 reads (33%) | catalogued as COSV62640204; called by muse, mutect2, varscan2
- AXDND1 | c.1813C>A p.L605I | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV62641732; called by muse, mutect2, varscan2
- B3GALT2 | c.981T>G p.I327M | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66463982; called by muse, mutect2, varscan2
- B3GLCT | c.993G>T p.L331F | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV100587310; called by muse, mutect2, varscan2
- B3GNT9 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99531342; called by muse, mutect2, varscan2
- B4GALNT2 | c.1571C>A p.S524Y | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV55925745; called by muse, mutect2, varscan2
- B4GALNT3 | c.1960G>A p.D654N | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1180114936, COSV99843035; called by muse, mutect2, varscan2
- B4GALT5 | c.764T>G p.F255C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100867017; called by muse, mutect2, varscan2
- B9D1 | c.404+2T>C p.X135_splice | Splice Site (SNP) | VAF 25/83 reads (30%) | catalogued as COSV99264947; called by muse, mutect2, varscan2
- BACH2 | c.1726C>T p.R576W | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57609411; called by muse, mutect2, varscan2
- BAHCC1 | c.4466G>A p.R1489H | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374320761, COSV100311654; called by muse, mutect2, varscan2
- BAIAP2L1 | c.287T>C p.F96S | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV50055390; called by muse, mutect2, varscan2
- BAMBI | c.166C>A p.L56I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs375455762; called by muse, mutect2, varscan2
- BAMBI | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs776749607, COSV65002903; called by muse, mutect2, varscan2
- BAMBI | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs369743386; called by muse, mutect2, varscan2
- BANP | c.755C>T p.A252V (on ENST00000286122; = p.A221V on NM_017869.4) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV53736574; called by muse, mutect2, varscan2
- BANP | c.1369G>A p.A457T (on ENST00000286122; = p.A407T on NM_017869.4) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs776799978, COSV53734622; called by muse, mutect2, varscan2
- BATF3 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.914); catalogued as rs1395373528, COSV54658069; called by muse, mutect2, varscan2
- BAZ1A | c.4438C>T p.R1480C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV62409067, COSV62409929; called by muse, mutect2, varscan2
- BBOX1 | c.641T>C p.V214A | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as COSV54190607; called by muse, mutect2, varscan2
- BBS12 | c.1801A>C p.T601P | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); catalogued as COSV58561868; called by muse, mutect2, varscan2
- BBS2 | c.1381G>A p.V461M | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs377000980; called by muse, mutect2, varscan2
- BBS2 | c.310G>T p.D104Y | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55326027; called by muse, mutect2, varscan2
- BBS4 | c.434A>G p.Y145C | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs764423333, COSV51437584; called by muse, mutect2, varscan2
- BBS9 | c.2293G>A p.E765K (on ENST00000242067 / NM_001348036.1; = p.E725K on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.341); catalogued as COSV99628149; called by muse, mutect2, varscan2
- BBX | c.140A>G p.D47G | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs900556346, COSV57882902; called by muse, mutect2, varscan2
- BBX | c.2584C>T p.L862F (on ENST00000325805 / NM_001142568.3; = p.L832F on NM_020235.7) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.949); catalogued as COSV57882915; called by muse, mutect2, varscan2
- BBX | c.2810C>T p.S937F (on ENST00000325805 / NM_001142568.3; = p.S907F on NM_020235.7) | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57882925; called by muse, mutect2, varscan2
- BCAN | c.863G>A p.G288D | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1198530003, COSV61256526; called by muse, mutect2, varscan2
- BCL2L13 | c.55G>A p.V19I | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as COSV58225537; called by muse, mutect2, varscan2
- BCL9L | c.2744C>T p.S915L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.484); catalogued as rs746679037, COSV52683734; called by muse, mutect2, varscan2
- BDKRB1 | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as rs376526644; called by muse, mutect2, varscan2
- BDP1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.406); catalogued as rs778000415, COSV100702735, COSV100703073; called by muse, mutect2, varscan2
- BEGAIN | c.642G>T p.E214D | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as COSV62068593; called by muse, varscan2
- BEND2 | c.1451G>A p.R484K | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV66215644, COSV66215770; called by mutect2, varscan2
- BEND4 | c.1130C>A p.A377D | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.122); catalogued as COSV72469046; called by muse, mutect2, varscan2
- BEND4 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV72469047; called by muse, mutect2, varscan2
- BEND6 | c.115G>T p.G39* | Nonsense Mutation (SNP) | VAF 32/94 reads (34%) | catalogued as COSV66068760, COSV66069287; called by muse, mutect2, varscan2
- BGN | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs782525620, COSV59036425; called by muse, mutect2, varscan2
- BGN | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs1418964197, COSV59036177; called by muse, mutect2, varscan2
- BHLHE40 | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.048); catalogued as rs775412121, COSV99848152; called by muse, mutect2, varscan2
- BICC1 | c.597T>G p.I199M | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65858692; called by muse, mutect2, varscan2
- BICD2 | c.2266G>A p.E756K | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV63548754; called by muse, mutect2, varscan2
- BIRC2 | c.758C>A p.S253Y | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV57161166; called by muse, mutect2, varscan2
- BIRC6 | c.5167G>A p.E1723K | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.706); catalogued as rs776666613, COSV70199361; called by muse, mutect2, varscan2
- BIRC6 | c.6380G>T p.R2127I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV70198317; called by muse, mutect2, varscan2
- BIRC6 | c.8876A>C p.K2959T | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV101428290; called by muse, varscan2
- BIVM-ERCC5 | c.3004G>A p.E1002K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.015); catalogued as rs770246574, COSV63246779; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4790C>T p.A1597V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs376411022, COSV63244831; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- BLM | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs139282091, COSV99049972; ClinVar: uncertain significance / not provided; called by mutect2, varscan2
- BLZF1 | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.024); catalogued as COSV100250618; called by muse, mutect2, varscan2
- BMP4 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs746984770, COSV55415564; called by muse, mutect2, varscan2
- BMPER | c.1588T>C p.S530P | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.418); catalogued as COSV99779611; called by muse, mutect2, varscan2
- BMPR2 | c.365T>C p.L122S | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.576); catalogued as COSV65808796; called by muse, mutect2, varscan2
- BMT2 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51775822, COSV51775977, COSV99774725; called by muse, mutect2, varscan2
- BMX | c.1843T>G p.L615V | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.614); catalogued as COSV59591112; called by muse, mutect2, varscan2
- BNC1 | c.1114C>A p.L372I | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61757173; called by muse, mutect2, varscan2
- BNC2 | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.078); catalogued as rs535983413, COSV66156428; called by muse, mutect2, varscan2
- BNIP2 | c.86T>C p.I29T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs762238174, COSV51105148; called by muse, mutect2, varscan2
- BOD1L1 | c.2366G>A p.R789Q | Missense Mutation (SNP) | VAF 100/282 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs751986426, COSV99239373; called by mutect2, varscan2
- BPIFB2 | c.1154T>C p.V385A | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV50064084; called by muse, mutect2, varscan2
- BPIFC | c.1149C>T p.F383= | Splice Region (SNP) | VAF 29/93 reads (31%) | catalogued as rs200868839, COSV55910552; called by muse, mutect2, varscan2
- BPTF | c.2411A>C p.K804T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV58835097; called by muse, mutect2, varscan2
- BPTF | c.2833G>T p.E945* | Nonsense Mutation (SNP) | VAF 40/95 reads (42%) | catalogued as COSV58835826; called by muse, mutect2, varscan2
- BPTF | c.3074A>C p.E1025A | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58835839; called by muse, mutect2, varscan2
- BRCA2 | c.794-1G>A p.X265_splice | Splice Site (SNP) | VAF 38/119 reads (32%) | catalogued as rs1233208888, COSV66452482; called by muse, mutect2, varscan2
- BRCA2 | c.1922C>A p.S641Y | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV66451054; called by muse, mutect2, varscan2
- BRCA2 | c.7559G>A p.R2520Q | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs80358982, COSV101203989, COSV66452497; ClinVar: uncertain significance / likely benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- BRCA2 | c.8858A>C p.E2953A | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV66452505; called by muse, mutect2, varscan2
- BRD1 | c.1591G>A p.D531N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781108454, COSV53456385, COSV53462476; called by muse, mutect2, varscan2
- BRD3 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57702323; called by muse, mutect2, varscan2
- BRD7 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV54266042; called by muse, mutect2, varscan2
- BRD7 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.23); catalogued as rs538440586, COSV67158432, COSV67158625; called by muse, mutect2, varscan2
- BRD8 | c.2216A>G p.D739G (on ENST00000254900 / NM_139199.2; = p.D812G on NM_006696.4) | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50147233; called by muse, mutect2, varscan2
- BRDT | c.508A>C p.K170Q | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.099); catalogued as COSV100746369; called by muse, mutect2, varscan2
- BRDT | c.1499A>C p.K500T | Missense Mutation (SNP) | VAF 68/246 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.597); catalogued as COSV62864516; called by muse, varscan2
- BRINP1 | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56297833; called by muse, mutect2, varscan2
- BRINP1 | c.1474C>A p.L492M | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV56297842, COSV56302232; called by muse, mutect2, varscan2
- BRINP1 | c.686-1G>T p.X229_splice | Splice Site (SNP) | VAF 24/67 reads (36%) | catalogued as COSV56297849; called by muse, mutect2, varscan2
- BRINP3 | c.2266A>G p.T756A | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV66521031; called by muse, varscan2
- BRINP3 | c.1928G>A p.S643N | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV66521036; called by muse, mutect2, varscan2
- BRIP1 | c.3623A>G p.D1208G | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.346); catalogued as COSV51998116; called by muse, mutect2, varscan2
- BRIP1 | c.2801T>G p.F934C | Missense Mutation (SNP) | VAF 55/197 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.16); catalogued as COSV51998136; called by muse, mutect2, varscan2
- BRIP1 | c.1069G>T p.E357* | Nonsense Mutation (SNP) | VAF 43/133 reads (32%) | catalogued as rs769081927, COSV51998155; called by muse, mutect2, varscan2
- BRPF3 | c.1708C>T p.R570W | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761546570, COSV60206960; called by muse, mutect2, varscan2
- BRS3 | c.653C>A p.S218Y | Missense Mutation (SNP) | VAF 62/100 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65710838, COSV65710893; called by muse, mutect2, varscan2
- BRWD1 | c.2624A>C p.N875T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV100313279, COSV60894759; called by muse, mutect2, varscan2
- BRWD3 | c.4627C>T p.R1543W | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs755270226, COSV64745068; called by muse, mutect2, varscan2
- BRWD3 | c.3976C>T p.R1326* | Nonsense Mutation (SNP) | VAF 40/73 reads (55%) | catalogued as rs866592729, COSV64746272; called by muse, mutect2, varscan2
- BSN | c.2686C>T p.R896C | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs140025841; called by muse, mutect2, varscan2
- BSN | c.5092C>T p.L1698F | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as COSV56512845, COSV56516394; called by muse, mutect2, varscan2
- BSN | c.7880G>A p.R2627H | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs750792473, COSV56516402; called by muse, mutect2, varscan2
- BSN | c.9706G>T p.D3236Y | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56516410; called by muse, mutect2, varscan2
- BSX | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1357349355, COSV58005053; called by muse, mutect2, varscan2
- BTAF1 | c.1525T>C p.C509R | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as COSV56432608; called by muse, mutect2, varscan2
- BTAF1 | c.1604G>A p.R535K | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56432622; called by muse, mutect2, varscan2
- BTBD1 | c.1268A>G p.Y423C | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55602666; called by muse, mutect2, varscan2
- BTBD11 | c.3109C>A p.L1037I (on ENST00000280758 / NM_001018072.2; = p.L574I on NM_001017523.2) | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.978); catalogued as COSV55022832; called by muse, mutect2, varscan2
- BTBD3 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs769315326, COSV54778889; called by muse, mutect2, varscan2
- BTBD8 | c.312G>T p.E104D | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV61546029; called by muse, mutect2, varscan2
- BTRC | c.1537C>T p.R513* (on ENST00000370187 / NM_033637.4; = p.R477* on NM_003939.5) | Nonsense Mutation (SNP) | VAF 30/106 reads (28%) | catalogued as rs568788208, COSV64579105; called by muse, varscan2
- BUB1 | c.2959G>A p.D987N | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1418232388, COSV57062953; called by muse, mutect2, varscan2
- BUB1B | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755579898, COSV55011588; called by muse, mutect2, varscan2
- BUB1B | c.3112G>A p.V1038I | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV55011607; called by muse, mutect2, varscan2
- C10orf120 | c.190T>G p.F64V | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.15); catalogued as COSV100271627; called by muse, mutect2, varscan2
- C10orf120 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs76198528, COSV100271629, COSV61492658; called by muse, mutect2, varscan2
- C10orf90 | c.1094C>A p.S365Y | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.325); catalogued as COSV52950938; called by muse, mutect2, varscan2
- C11orf54 | c.898C>A p.L300I (on ENST00000331239; = p.L250I on NM_014039.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.188); catalogued as COSV58680183; called by muse, mutect2, varscan2
- C11orf65 | c.503G>T p.R168I | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67596846, COSV67597315; called by muse, mutect2, varscan2
- C12orf40 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760100213, COSV61129961; called by muse, varscan2
- C12orf50 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs776851924, COSV53893621; called by muse, mutect2, varscan2
- C12orf50 | c.431C>A p.A144E | Missense Mutation (SNP) | VAF 76/242 reads (31%) | SIFT tolerated (0.86); PolyPhen benign (0.143); catalogued as COSV53894794; called by muse, mutect2, varscan2
- C12orf66 | c.509A>C p.K170T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as COSV100320741; called by muse, mutect2, varscan2
- C15orf39 | c.454A>C p.K152Q | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV62296390; called by muse, mutect2, varscan2
- C16orf46 | c.106A>C p.S36R | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as COSV55150831; called by muse, mutect2, varscan2
- C16orf71 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as rs765725967, COSV58508426; called by muse, mutect2, varscan2
- C16orf72 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs1039176829, COSV59915897; called by muse, mutect2, varscan2
- C16orf86 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54675826; called by muse, mutect2, varscan2
- C17orf49 | c.262T>G p.S88A | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1567725089, COSV66080883; called by muse, mutect2, varscan2
- C17orf67 | c.248A>G p.D83G | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.38); catalogued as COSV101190968; called by muse, mutect2, varscan2
- C17orf75 | c.574A>C p.K192Q | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as COSV56752664; called by muse, mutect2, varscan2
- C19orf18 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs146255633, COSV58705690; called by muse, mutect2, varscan2
- C1GALT1C1 | c.749C>A p.S250Y | Missense Mutation (SNP) | VAF 51/74 reads (69%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.698); catalogued as COSV58974017; called by muse, mutect2, varscan2
- C1GALT1C1L | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs910474337, COSV56749520; called by muse, mutect2, varscan2
- C1orf100 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0.023); catalogued as rs762477027, COSV57374505; called by muse, mutect2, varscan2
- C1orf116 | c.1577C>A p.S526Y | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs1374383203, COSV63943979, COSV63944056; called by muse, mutect2, varscan2
- C1orf127 | c.1357C>A p.L453I | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV65437171; called by muse, mutect2, varscan2
- C1orf131 | c.778T>G p.L260V | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.651); catalogued as COSV59642183; called by muse, mutect2, varscan2
- C1orf141 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.199); catalogued as rs752539243, COSV63992303; called by muse, varscan2
- C1orf146 | c.23A>C p.K8T | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.076); catalogued as rs1421808388, COSV100951848; called by muse, varscan2
- C1orf158 | c.140A>G p.Q47R | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.132); catalogued as COSV55346068; called by muse, mutect2, varscan2
- C1orf158 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); catalogued as rs757604143, COSV55346313, COSV55347418; called by muse, mutect2, varscan2
- C1orf43 | c.71T>G p.F24C | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV55171331; called by muse, varscan2
- C20orf194 | c.3285G>T p.K1095N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52694766; called by muse, mutect2, varscan2
- C22orf23 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV50777821, COSV99970222; called by muse, mutect2, varscan2
- C2CD5 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1358127069, COSV61724153; called by muse, mutect2, varscan2
- C2CD6 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.121); catalogued as rs147236648; called by muse, mutect2, varscan2
- C2orf16 | c.37A>C p.N13H | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV68840580; called by muse, mutect2, varscan2
- C2orf16 | c.4357C>T p.R1453* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as rs557771429, COSV62673324; called by muse, mutect2, varscan2
- C3 | c.2368C>A p.L790I | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV55571782; called by muse, mutect2, varscan2
- C3 | c.2036G>A p.R679Q | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs760637447, COSV55571795; called by muse, mutect2, varscan2
- C3orf20 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs777709119, COSV53782660; called by muse, mutect2, varscan2
- C3orf20 | c.2095C>T p.R699C | Missense Mutation (SNP) | VAF 65/130 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as rs1041167391, COSV53784595, COSV99037587; called by muse, mutect2, varscan2
- C3orf33 | c.254G>A p.R85Q (on ENST00000340171 / NM_001308229.2; = p.R42Q on NM_173657.2) | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs547864770, COSV60896792; called by muse, mutect2, varscan2
- C5 | c.3616C>T p.R1206C | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1402957355, COSV56324454; called by muse, mutect2, varscan2
- C5 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs544818019, COSV56326412; called by muse, mutect2, varscan2
- C5orf51 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370411797, COSV101069011; called by muse, mutect2, varscan2
- C6orf120 | c.515A>G p.E172G | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV100179137; called by muse, mutect2, varscan2
- C6orf15 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as rs111832758, COSV52537833; called by muse, mutect2, varscan2
- C6orf58 | c.699A>C p.E233D | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV61666386; called by muse, mutect2, varscan2
- C6orf58 | c.889C>T p.L297F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV100314879, COSV61667524; called by muse, mutect2
- C7 | c.1000G>T p.E334* | Nonsense Mutation (SNP) | VAF 20/73 reads (27%) | catalogued as COSV57470260; called by muse, mutect2, varscan2
- C7 | c.1846G>T p.D616Y | Missense Mutation (SNP) | VAF 70/233 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV57473496, COSV57477539; called by muse, mutect2, varscan2
- C7orf31 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs774680315, COSV52218656; called by muse, mutect2, varscan2
- C7orf57 | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as COSV100817269; called by muse, varscan2
- C8A | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs201034819, COSV63483573; called by muse, mutect2, varscan2
- C8B | c.875T>C p.F292S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV64777346; called by muse, mutect2, varscan2
- C8B | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.078); catalogued as rs770507328, COSV64777350; called by muse, mutect2, varscan2
- C8orf33 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs367787964, COSV58895529; called by muse, mutect2, varscan2
- C8orf34 | c.1107G>A p.E369= | Splice Region (SNP) | VAF 16/38 reads (42%) | catalogued as COSV104397540, COSV57401744; called by muse, mutect2, varscan2
- C8orf37 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs149558233; called by muse, varscan2
- C9orf43 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs538217577, COSV55912476; called by muse, mutect2, varscan2
- C9orf72 | c.1286C>A p.S429Y | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV66163381; called by muse, mutect2, varscan2
- C9orf72 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV66154636; called by muse, mutect2, varscan2
- C9orf78 | c.415C>A p.P139T | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.038); catalogued as COSV59613117; called by muse, mutect2, varscan2
- CA13 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs912405909, COSV58797284; called by muse, mutect2, varscan2
- CA2 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 72/208 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53406485; called by muse, mutect2, varscan2
- CA3 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as rs779091963, COSV99570699; called by muse, mutect2, varscan2
- CA8 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs201131573, COSV58771470; called by muse, mutect2, varscan2
- CABIN1 | c.1277A>G p.D426G | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV99573217; called by muse, mutect2, varscan2
- CABIN1 | c.5026C>T p.P1676S | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV54080728; called by muse, mutect2, varscan2
- CABLES2 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as rs1429640918, COSV54156467; called by muse, mutect2, varscan2
- CABYR | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs868264529, COSV100510061; called by muse, mutect2, varscan2
- CACHD1 | c.887A>C p.K296T | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as COSV51552073; called by muse, mutect2, varscan2
- CACNA1B | c.5497C>T p.P1833S | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV99497436; called by muse, varscan2
- CACNA1D | c.577G>C p.V193L | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55444451; called by muse, mutect2, varscan2
- CACNA1D | c.3478G>T p.E1160* (on ENST00000350061 / NM_001128840.3; = p.E1180* on NM_000720.4) | Nonsense Mutation (SNP) | VAF 39/104 reads (38%) | catalogued as COSV55440576; called by muse, mutect2, varscan2
- CACNA1E | c.2482C>T p.R828W | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV62381010; called by muse, mutect2, varscan2
- CACNA1F | c.3904C>T p.R1302W | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782005253, COSV59904055; called by muse, mutect2, varscan2
- CACNA1S | c.4099C>T p.L1367F | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62938760; called by muse, mutect2, varscan2
- CACNA1S | c.51G>T p.K17N | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62938768; called by muse, mutect2, varscan2
- CACNA2D1 | c.2018C>T p.S673L (on ENST00000356253 / NM_001366867.1; = p.S661L on NM_000722.4) | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs779137994, COSV62373938; called by muse, mutect2, varscan2
- CACNA2D3 | c.675G>A p.P225= | Splice Region (SNP) | VAF 20/81 reads (25%) | catalogued as rs562359468, COSV55531666, COSV99870579; called by muse, mutect2, varscan2
- CACNG1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.385); catalogued as rs760216442, COSV56826298, COSV56827091; called by muse, mutect2, varscan2
- CACNG5 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as rs993681024, COSV99400588; called by muse, mutect2, varscan2
- CACNG8 | c.293G>T p.R98I | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV54414517, COSV99554947; called by muse, mutect2, varscan2
- CADPS | c.3493A>C p.K1165Q | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV51876080; called by muse, varscan2
- CADPS2 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs373213538; called by muse, mutect2, varscan2
- CALD1 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV62647153; called by muse, mutect2, varscan2
- CALD1 | c.1417G>T p.E473* (on ENST00000361675 / NM_033138.4; = p.E218* on NM_004342.7) | Nonsense Mutation (SNP) | VAF 22/86 reads (26%) | catalogued as COSV62647166; called by muse, mutect2, varscan2
- CALD1 | c.1777C>T p.R593* (on ENST00000361675 / NM_033138.4; = p.R338* on NM_004342.7) | Nonsense Mutation (SNP) | VAF 24/99 reads (24%) | catalogued as COSV62647174; called by muse, mutect2, varscan2
- CALM2 | c.43G>T p.E15* | Nonsense Mutation (SNP) | VAF 64/218 reads (29%) | catalogued as COSV55399209; called by muse, mutect2, varscan2
- CALR3 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1247489343, COSV99522187; ClinVar: uncertain significance; called by muse, varscan2
- CALU | c.910G>T p.D304Y | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV50821571; called by muse, mutect2, varscan2
- CAMK1D | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs148446769; called by mutect2, varscan2
- CAMK2G | c.1277G>A p.R426Q (on ENST00000423381 / NM_001367518.1; = p.R363Q on NM_001222.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.382); catalogued as rs760411599, COSV59481370; called by muse, varscan2
- CAMK2G | c.578A>C p.K193T | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99989826; called by muse, mutect2, varscan2
- CAMKK2 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV61214188; called by muse, mutect2, varscan2
- CAMKV | c.474G>T p.K158N | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.097); catalogued as COSV99615530; called by muse, mutect2, varscan2
- CAMLG | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.946); catalogued as rs751766092, COSV51804541; called by muse, mutect2, varscan2
- CAMLG | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765331970, COSV51804427; called by muse, mutect2, varscan2
- CAMP | c.464G>T p.R155I (on ENST00000296435; = p.R152I on NM_004345.5) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs760073514, COSV56481942, COSV99601226; called by muse, mutect2, varscan2
- CAMSAP1 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.13); catalogued as rs754501371, COSV56721545; called by muse, mutect2, varscan2
- CAMSAP1 | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 9/41 reads (22%) | catalogued as COSV56721558, COSV56727091; called by muse, mutect2, varscan2
- CAMSAP2 | c.2939C>A p.S980Y (on ENST00000236925 / NM_001297707.2; = p.S969Y on NM_203459.3) | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as rs764735613, COSV52669550; called by muse, mutect2, varscan2
- CAMSAP3 | c.3265G>A p.E1089K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs549080555, COSV50332923; called by muse, mutect2, varscan2
- CAMTA1 | c.1762G>A p.A588T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs754356402, COSV57895728; called by muse, mutect2, varscan2
- CAND1 | c.1651C>T p.R551C | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV73389562; called by muse, mutect2, varscan2
- CANT1 | c.1055A>G p.N352S | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV56605392; called by muse, mutect2, varscan2
- CANX | c.699G>T p.K233N | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV99910450; called by muse, mutect2, varscan2
- CAP1 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 38/124 reads (31%) | catalogued as COSV61222892; called by muse, mutect2, varscan2
- CAPN6 | c.956A>G p.D319G | Missense Mutation (SNP) | VAF 35/46 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs112040915, COSV100136877; called by muse, mutect2, varscan2
- CAPNS2 | c.383T>C p.V128A | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs766891009, COSV50895144; called by muse, mutect2, varscan2
- CAPZA3 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs770419225, COSV56851706; called by muse, mutect2, varscan2
- CAPZB | c.667A>G p.K223E | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV51646362; called by muse, mutect2, varscan2
- CARD11 | c.2917C>T p.R973C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.634); catalogued as rs754645078, COSV67797709; called by muse, mutect2, varscan2
- CARF | c.1820C>A p.S607Y | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as rs1559289266, COSV57547173; called by muse, mutect2, varscan2
- CARNMT1 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 30/97 reads (31%) | catalogued as COSV65190287; called by muse, mutect2, varscan2
- CARS1 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53453427; called by muse, mutect2, varscan2
- CASKIN1 | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.667); catalogued as COSV58871885; called by muse, mutect2, varscan2
- CASP4 | c.392G>T p.R131I | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as COSV101274142; called by mutect2, varscan2
- CASP8AP2 | c.4067C>T p.A1356V | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1400256539, COSV52746488; called by muse, mutect2, varscan2
- CASR | c.486T>G p.I162M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.712); catalogued as COSV56136706; called by muse, varscan2
- CASS4 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as rs1484376120, COSV64386085; called by muse, mutect2, varscan2
- CATSPER1 | c.2188A>G p.T730A | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as COSV56410231; called by muse, mutect2, varscan2
6,498 further variants in this file (4,840 protein-altering or splice-affecting, 1,512 silent, 146 other) are not listed here.
